Somatic mutation profile of tumor specimen TCGA-AX-A3FZ-01A (aliquot TCGA-AX-A3FZ-01A-11D-A228-09) from TCGA case TCGA-AX-A3FZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 33.8 years (12,331 days).
Specimen TCGA-AX-A3FZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8422d911-9ca6-4d58-90be-092fe1d51688.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3FZ-10A (Blood Derived Normal), aliquot TCGA-AX-A3FZ-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd6d0e98-c68b-4b7e-9c5f-2b1cbd7b0729

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 67/99 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 112/122 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 91/95 reads (96%) | catalogued as rs587778858, CM951107, COSV57307024; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.714T>G p.C238W | Missense Mutation (SNP) | VAF 77/84 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193920789, COSV52680696, COSV52840491, COSV53234319, COSV53865082; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABI3 | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99865437; called by muse, mutect2, varscan2
- ATP7A | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100430606; called by muse, mutect2, varscan2
- CRTC1 | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs778913373, COSV58724018; called by muse, mutect2, varscan2
- ESRP1 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as rs772941059, COSV100619262; called by muse, mutect2, varscan2
- ETAA1 | c.2230A>C p.N744H | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99712688; called by muse, mutect2, varscan2
- FAM189A2 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs971223241, COSV99974920; called by muse, mutect2, varscan2
- FGR | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs777247084, COSV100925800; called by muse, mutect2, varscan2
- FTHL17 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV63266778, COSV63267286; called by muse, mutect2, varscan2
- GABRA2 | c.399dup p.S134Ifs*5 | Frame Shift Ins (INS) | VAF 22/117 reads (19%) | catalogued as rs747927440; called by mutect2, pindel, varscan2
- GBP2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs1399908290, COSV100975371; called by muse, mutect2, varscan2
- HDC | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1228488372, COSV99983877; called by muse, mutect2, varscan2
- LRP1 | c.12038G>A p.G4013E | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99675440; called by muse, mutect2, varscan2
- LRRC43 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs942534186, COSV60289174; called by muse, mutect2, varscan2
- MECOM | c.613C>T p.R205C (on ENST00000468789 / NM_001105078.4; = p.R393C on NM_004991.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201758074, COSV52963046, COSV52964249, COSV52973072; called by muse, mutect2, varscan2
- MED12 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100377259; called by muse, mutect2
- MYO5B | c.5180A>C p.N1727T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99544367; called by muse, mutect2, varscan2
- PASD1 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100949254; called by muse, mutect2, varscan2
- PTPN18 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99447658; called by muse, mutect2, varscan2
- ROBO1 | c.3487C>A p.Q1163K | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV101458532; called by muse, mutect2, varscan2
- SCAI | c.1598G>A p.G533E (on ENST00000336505 / NM_001144877.3; = p.G556E on NM_173690.5) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100332467; called by muse, mutect2, varscan2
- SLC7A13 | c.817+1G>T p.X273_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99878758; called by muse, mutect2, varscan2
- STOX1 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV100057755; called by muse, mutect2, varscan2
- TAF6 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 117/231 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59840551; called by muse, mutect2, varscan2
- TOP3B | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100592452; called by muse, mutect2, varscan2
- TTN | c.40645G>A p.V13549I (on ENST00000591111; = p.V6125I on NM_003319.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | PolyPhen benign (0.236); catalogued as rs776996868, COSV60032757; called by muse, mutect2, varscan2
- UBR4 | c.7387G>A p.D2463N | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.083); catalogued as rs916816131, COSV100920676; called by muse, mutect2, varscan2
- WDR74 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs765155158, COSV99613968; called by muse, mutect2, varscan2
- ARID1A | c.2186_2199delinsT p.P729Lfs*9 | Frame Shift Del (DEL) | VAF 48/77 reads (62%) | called by pindel, varscan2*
- SLC24A4 | c.318+1del p.X106_splice | Splice Site (DEL) | VAF 28/91 reads (31%) | called by mutect2, pindel, varscan2
- AR | c.609C>T p.S203= | Silent (SNP) | VAF 65/113 reads (58%) | catalogued as COSV101017927; called by muse, mutect2, varscan2
- C3orf56 | c.321C>T p.G107= | Silent (SNP) | VAF 121/188 reads (64%) | catalogued as rs534363917, COSV67756200; called by muse, mutect2, varscan2
- CELSR3 | c.6624G>A p.L2208= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99373231; called by muse, mutect2, varscan2
- GCNA | c.354A>G p.E118= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV101032484; called by muse, mutect2
- MED12 | c.42G>A p.L14= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100377261; called by muse, mutect2
- PAQR7 | c.216C>T p.A72= | Silent (SNP) | VAF 66/169 reads (39%) | catalogued as rs376473466; called by muse, mutect2, varscan2
- SLC12A7 | c.1383G>A p.T461= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as rs559963983, COSV99369681; called by muse, varscan2
- SVIL | c.2523G>C p.T841= (on ENST00000355867 / NM_021738.3; = p.T415= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/158 reads (57%) | catalogued as COSV100881188; called by muse, mutect2, varscan2
- TRAP1 | c.1656G>A p.T552= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs762072656, COSV99893371; called by muse, mutect2, varscan2
- TRIM50 | c.381C>G p.T127= | Silent (SNP) | VAF 19/366 reads (5%) | catalogued as COSV52721815, COSV99333899; called by muse, mutect2
- TRPM5 | c.3255G>A p.V1085= | Silent (SNP) | VAF 39/62 reads (63%) | catalogued as COSV99329959; called by muse, mutect2, varscan2
